Somatic mutation profile of tumor specimen TCGA-3B-A9HS-01A (aliquot TCGA-3B-A9HS-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9HS, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Myxoid leiomyosarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.1 years (21,946 days).
Specimen TCGA-3B-A9HS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fc50699-cd84-46ba-a5c3-9eef5eb80fe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HS-10A (Blood Derived Normal), aliquot TCGA-3B-A9HS-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/995eab27-c676-4fec-888c-53553fa9fedb

The open-access MAF lists 60 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 40, Silent 15, Nonsense Mutation 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACD | c.1489G>A p.G497S (on ENST00000620338; = p.G408S on NM_022914.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV99537505; called by muse, mutect2, varscan2
- ADGRF5 | c.1990G>T p.G664W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99345103; called by muse, mutect2, varscan2
- AGAP2 | c.828G>C p.L276F | Missense Mutation (SNP) | VAF 48/1720 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV99222483, COSV99224384; called by muse, mutect2
- ARHGEF28 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99708383; called by muse, mutect2, varscan2
- ATRX | c.3758C>G p.S1253* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as COSV100970239; called by muse, mutect2
- BGLAP | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs750302867, COSV52745491; called by muse, varscan2
- CCN2 | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100915290; called by muse, mutect2, varscan2
- CCPG1 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100196993; called by muse, mutect2, varscan2
- CECR2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99377279; called by muse, mutect2, varscan2
- CELSR1 | c.4311G>T p.R1437S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as rs761007560, COSV99417204; called by muse, mutect2, varscan2
- COL4A6 | c.3142G>T p.G1048C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774388681, COSV100563569; called by muse, mutect2, varscan2
- CPA2 | c.146A>T p.H49L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99743833; called by muse, mutect2, varscan2
- DAB2 | c.53C>G p.A18G | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100297834, COSV57914544; called by muse, mutect2, varscan2
- DBT | c.1211T>C p.I404T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100923434; called by muse, mutect2, varscan2
- EEA1 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100467238; called by muse, mutect2, varscan2
- ITGAD | c.2725G>C p.A909P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV101210370; called by muse, mutect2, varscan2
- KIF16B | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs762217307, COSV100733906; called by muse, mutect2, varscan2
- KRBA1 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as COSV99752313; called by muse, mutect2, varscan2
- LMNB1 | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99745690; called by muse, mutect2, varscan2
- MAGEB16 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.77); PolyPhen benign (0.06); catalogued as COSV101303287; called by muse, varscan2
- MAL | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100015652; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3454G>C p.V1152L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99167768; called by muse, mutect2, varscan2
- MCM3 | c.1006G>A p.E336K (on ENST00000229854 / NM_001366374.2; = p.E326K on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100008640; called by muse, mutect2, varscan2
- MKI67 | c.3992G>A p.R1331K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as COSV100896287; called by muse, mutect2, varscan2
- ORC1 | c.1178A>T p.Q393L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100856617; called by muse, mutect2
- OVOL1 | c.412A>T p.K138* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100256762; called by muse, mutect2, varscan2
- PALLD | c.3340G>T p.A1114S (on ENST00000505667 / NM_001166108.2; = p.A1097S on NM_016081.4) | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99824104; called by muse, mutect2
- PHKA2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101176791; called by muse, mutect2
- PLEKHA5 | c.2179T>A p.Y727N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.379); catalogued as COSV54704452; called by muse, mutect2, varscan2
- PNPLA4 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as COSV101124366; called by muse, mutect2
- PRAMEF12 | c.1343T>A p.I448K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100743083; called by mutect2, varscan2
- RAET1G | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV100951643; called by muse, mutect2, varscan2
- RP1 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99606593; called by mutect2, varscan2
- RRN3 | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99548688; called by muse, mutect2, varscan2
- SLC17A8 | c.1413G>C p.M471I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100035278; called by muse, mutect2, varscan2
- TIE1 | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767153303, COSV100992024; called by muse, mutect2, varscan2
- USH2A | c.7720C>A p.L2574I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV100230847; called by muse, mutect2
- VIPAS39 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99375876; called by muse, mutect2, varscan2
- VIPAS39 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV99375877; called by muse, mutect2
- WDR83 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV99269543; called by muse, varscan2
- ZNF521 | c.2171G>A p.C724Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329406123, COSV100831582, COSV100833015; called by mutect2, varscan2
- CCL16 | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- ITPK1 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 56/72 reads (78%) | SIFT tolerated (0.5); PolyPhen benign (0); called by mutect2, varscan2
- TMEM236 | c.908T>G p.F303C | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.275); called by muse, mutect2
- ZNF284 | c.623dup p.C208Wfs*2 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- ABHD16B | c.45G>A p.K15= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99410568; called by muse, varscan2
- AGAP2 | c.1065C>T p.S355= | Silent (SNP) | VAF 132/1398 reads (9%) | catalogued as COSV99222477; called by muse, mutect2
- BAZ2A | c.42T>C p.L14= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV51643767; called by muse, mutect2
- CORIN | c.2493C>T p.V831= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99903123; called by muse, mutect2, varscan2
- CRISP1 | c.132C>T p.I44= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV59993170; called by muse, mutect2
- DCSTAMP | c.1212G>A p.V404= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV52578984; called by muse, mutect2, varscan2
- F8 | c.909G>A p.A303= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs782276776, COSV100811328; called by muse, mutect2
- FCSK | c.822G>A p.E274= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99850605; called by muse, mutect2, varscan2
- ISYNA1 | c.987C>T p.I329= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1447293503, COSV54209998; called by muse, mutect2
- LILRB5 | c.927C>T p.S309= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as rs535392919, COSV100300164; called by muse, mutect2, varscan2
- MUC16 | c.9495G>T p.V3165= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV101198679; called by muse, mutect2, varscan2
- NOTCH3 | c.4530C>T p.R1510= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99655891; called by muse, mutect2, varscan2
- STK31 | c.2499G>A p.K833= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100669195; called by muse, mutect2
- TRIM17 | c.153G>A p.K51= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV54382680, COSV99694581; called by muse, mutect2
- ZNF605 | c.1869G>T p.G623= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100053513; called by muse, mutect2, varscan2
